Gene-level copy-number profile of tumor specimen AP-UG7J-VM from APOLLO case AP-UG7J, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2.
Specimen AP-UG7J-VM: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6f87bb0b-345f-455c-a8a7-e328062bee1d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-UG7J-KT (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/1b9a7201-dedb-4ac2-abf5-28501b9ac5c5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 4,114; copy number 2: 20,180; copy number 3: 19,372; copy number 4: 10,125; copy number 5: 2,600; copy number 6: 1,120; copy number 7: 773; copy number 8: 26; copy number 9: 9; copy number 14: 1; copy number 19: 23; copy number 21: 20; copy number 22: 3; copy number 26: 13.

Homozygous deletions (total copy number 0; autosomes only): 55 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:89,991,831–91,354,579, 20 genes: PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049, RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1.
- chr21:7,744,962–8,603,984, 27 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68.
- chr22:48,274,364–49,266,080, 8 genes: MIR3201, Z82249.1, TAFA5, Z84468.1, MIR4535, LINC01310, RPL35P8, Z82202.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 868 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:19,510,593–19,510,733, 1 gene, copy number 14: RNU4-28P.
- chr4:51,843,000–55,125,595, 59 genes, copy number 19–26: DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR.
- chr9:30,670,964–31,506,615, 12 genes, copy number 8–9: CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30.
- chr19:18,607,430–19,192,158, 21 genes, copy number 7 (within-gene range 2–7): TMEM59L, RN7SL155P, KLHL26, CRTC1, COMP, UPF1, GDF1, CERS1, AC005197.1, COPE, AC002985.1, DDX49, HOMER3, HOMER3-AS1, RN7SL70P, SUGP2, ARMC6, SLC25A42, TMEM161A, MEF2B, BORCS8-MEF2B.
- chr19:19,512,418–19,643,657, 10 genes, copy number 7: TSSK6, NDUFA13, AC011448.1, YJEFN3, CILP2, PBX4, PHF5CP, AC002306.1, LPAR2, GMIP.
- chr21:23,352,929–30,643,136, 132 genes, copy number 7 (broad region; genes not listed).
- chr21:32,259,804–44,298,648, 295 genes, copy number 7 (broad region; genes not listed).
- chr21:46,093,264–46,228,824, 7 genes, copy number 7 (within-gene range 6–7): AP001471.1, COL6A2, FTCD, FTCD-AS1, SPATC1L, AP001468.1, LSS.
- chr22:20,917,407–22,687,271, 154 genes, copy number 7 (broad region; genes not listed).
- chr22:23,856,703–23,895,223, 4 genes, copy number 7 (within-gene range 4–7): SLC2A11, AP000350.4, AP000350.8, RN7SL268P.
- chr22:23,926,900–24,270,134, 22 genes, copy number 8: AP000350.2, AP000350.1, AP000350.3, GSTT2B, AC253536.2, DDTL, AC253536.6, DDT, AC253536.7, AC253536.1, AC253536.5, GSTT2, GSTT4, AC253536.4, CABIN1, AC253536.3, SUSD2, GGT5, GGTLC4P, POM121L9P, BCRP1, AP000354.1.
- chr22:29,505,879–30,378,658, 33 genes, copy number 7 (within-gene range 4–7): THOC5, AC005529.1, NIPSNAP1, NF2, RPEP4, AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA, AC004882.3, UQCR10, ASCC2, MTMR3, RNU6-331P, AC003681.1, MIR6818, HORMAD2-AS1, CNN2P1, HORMAD2, AC003071.1, RPS3AP51, AC002378.1, LIF-AS1, LIF, AC004264.1, OSM, AC004264.2, CASTOR1, AC004997.1, TBC1D10A, SF3A1, CCDC157.
- chr22:30,969,245–31,292,534, 23 genes, copy number 7 (within-gene range 4–7): TUG1, AC004542.5, AC004542.4, AC004542.6, AC004542.3, AC004542.2, AC004542.1, AC005005.4, RN7SL633P, SMTN, AC005005.3, SELENOM, AC005005.2, INPP5J, PLA2G3, AC005005.1, MIR3928, RNF185, RNF185-AS1, LIMK2, RNU6-1128P, Y_RNA, PIK3IP1.
- chr22:35,738,736–36,139,350, 7 genes, copy number 7: RBFOX2, NDUFA9P1, Z82217.1, Z95114.4, Z95114.1, Z95114.2, Z95114.3.
- chr22:36,560,857–36,703,752, 1 gene, copy number 7 (within-gene range 3–7): CACNG2.
- chr22:36,703,918–38,570,204, 86 genes, copy number 7 (broad region; genes not listed).
- chr22:42,364,390–42,369,284, 1 gene, copy number 8: LINC01315.

Autosomal genes at a single copy (total copy number 1): 3,239. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
